Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JI, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JI-01A (Primary Tumor).

[page 1 of 2]
ICD-03

Carcinoma, infiltrating, ductal, NOS 8500/3

Site: breast, NOS C50.9 3/11/11 p

page 1 / 2

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: 1. Multiple organ resection – right breast and axillary tissue

Unit in charge:

Physician in charge:

Material collected on:

Material received on

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast

HIFAA Discrepancy		X
Reviewed (Initials)	Date Reviewed: 3/11/11	

[page 2 of 2]
Examination performed on

Macroscopic description:

Right breast sized 35 x 23 x 9 cm removed along with axillary tissues sized 13 x 8 x 4 cm and a skin flap of 24 x 17 cm. Weight 1,400 g.

Tumour sized 1.9 x 1.4 x 1.8 cm in the upper outer quadrant, 6 cm from the upper boundary, 2 cm from the base and 1.8 cm from the front surface. Lymph nodes 2.4 cm in length.

Microscopic description:

Carcinoma ductale invasivum - NHG1 (2 + 3 +1: 2 mitoses/ 10 HPF, visual area diameter 0.57 mm). Glandular tissue, outside the tumour, showing lesions of the type mastopathia fibrosa et cystica, hyperplasia ductalis simplex (ADH), adenosis sclerosans.

AXILLARY LYMPH NODES:

Metastases carcinomatosae in lymphonodis (No II/XXII).

Infiltratio capsulae lymphonodi et telae perinodalis.

Emboliae carcinomatosae vasorum.

Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the left breast

Metastases carcinomatosae in lymphonodis axillae (No II/XXII). Cancer metastases in axillary lymph nodes (No II/XXII)

Invasivo carcinomatosa vasorum. Vascular invasion (NHG2, pT1c, pN1a).

Compliance validated by:

Results of immunohistochemical examination:

Estrogen receptors found in 10-75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive carcinoma cells (Score = 1+)

Compliance validated by:

Source: NCI Genomic Data Commons file 1eaf1fb5-fa16-4242-9e4b-66279d2d3df5 (TCGA-D8-A1JI.EF2DC6FB-F026-4025-B148-DF07194914AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).